Somatic mutation profile of tumor specimen BA2753D (aliquot aq-BA2753D) from BEATAML1.0 case 2406, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.8 years (22,196 days).
Specimen BA2753D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8b5388d-f710-44aa-a9fe-e1cfcdf33c06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2774D (Solid Tissue Normal), aliquot aq-BA2774D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc973d0e-587d-4cb0-afde-b7d8d4a5d206

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Frame Shift Ins 3, Nonsense Mutation 2, 3'UTR 1, 5'UTR 1, Intron 1, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 12/112 reads (11%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- ADGRL4 | c.784T>G p.S262A | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV66067030; called by muse, mutect2, varscan2
- DOCK6 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.91); catalogued as rs376149847; called by muse, mutect2, varscan2
- GALNT5 | c.2267A>G p.Y756C | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1467006307; called by muse, mutect2, varscan2
- GBP5 | c.1517C>G p.A506G | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as COSV58594073; called by muse, mutect2, varscan2
- GPR62 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs1434295950; called by muse, varscan2
- INTS11 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs995020000; called by muse, mutect2, varscan2
- NRK | c.1243G>C p.V415L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54592268; called by muse, mutect2, varscan2
- PHF6 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 52/302 reads (17%) | catalogued as COSV59700130; called by muse, mutect2, varscan2
- PKP1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.565); catalogued as rs373286108; called by muse, mutect2, varscan2
- RELN | c.9113G>A p.R3038H | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV59029814; called by muse, mutect2, varscan2
- STAG2 | c.1197-1G>A p.X399_splice | Splice Site (SNP) | VAF 19/98 reads (19%) | catalogued as COSV54362650; called by muse, mutect2, varscan2
- SUN5 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 34/133 reads (26%) | catalogued as rs772515844, COSV62180114; called by muse, mutect2, varscan2
- WT1 | c.1187_1188insC p.L396Ffs*11 | Frame Shift Ins (INS) | VAF 31/213 reads (15%) | catalogued as COSV60069881, COSV60076829; called by pindel, varscan2
- WT1 | c.1068dup p.R357Afs*16 | Frame Shift Ins (INS) | VAF 28/152 reads (18%) | catalogued as COSV60069248, COSV60072819, COSV60075216, COSV60083033, COSV99070052, COSV99070055; called by pindel, varscan2
- ANO1 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRYBB1 | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FAM131C | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRTAP13-1 | c.276_292del p.C92Wfs*58 | Frame Shift Del (DEL) | VAF 22/139 reads (16%) | called by mutect2, pindel, varscan2
- NEFL | c.434A>C p.D145A | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR4B1 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKD1L1 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLXNB3 | c.4754A>T p.H1585L | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A20 | c.448A>T p.T150S | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMCO2 | c.429A>C p.E143D | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ADCY9 | c.3522C>T p.A1174= | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as rs200368797; ClinVar: likely benign; called by muse, mutect2, varscan2
- INO80B | c.909A>C p.S303= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2
- OR52K2 | c.882T>C p.Y294= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- PCDHGC5 | c.558A>G p.K186= | Silent (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- RNF13 | c.378T>A p.S126= | Silent (SNP) | VAF 28/128 reads (22%) | called by muse, mutect2, varscan2
- ZNF280A | c.420G>A p.S140= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as rs748149128; called by muse, mutect2, varscan2
- MIR520A | n.78G>A | RNA (SNP) | VAF 16/88 reads (18%) | catalogued as rs534597914; called by muse, mutect2, varscan2
- RNF166 | c.648+54_648+56del | Intron (DEL) | VAF 12/92 reads (13%) | catalogued as rs1344292926; called by pindel, varscan2
- SERBP1 | c.*20C>T | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- TMEM167B | c.-68C>T | 5'UTR (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
